Somatic mutation profile of tumor specimen MMRF_1645_1_BM_CD138pos (aliquot MMRF_1645_1_BM_CD138pos_T1_KBS5U_L04822) from MMRF case MMRF_1645, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.1 years (13,200 days).
Specimen MMRF_1645_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 162aa8a6-9749-4739-8d0b-73d7d424c724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1645_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1645_1_PB_Whole_C3_KBS5U_L04834; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5db71c5-a139-4499-a1e8-83467fdbbf77

The open-access MAF lists 57 somatic variants for this specimen: 20 protein-altering or splice-affecting, 12 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 17, Silent 12, Intron 3, 5'Flank 3, Translation Start Site 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs374021595; called by muse, mutect2, varscan2
- DLC1 | c.3250G>A p.V1084M (on ENST00000276297 / NM_001348081.2; = p.V647M on NM_006094.5) | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs774780095, COSV52297787; called by muse, mutect2, varscan2
- DNMT3A | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs1459396018, COSV53044586; called by muse, mutect2
- EYS | c.2288G>C p.W763S | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65563346; called by muse, mutect2, varscan2
- IGHV2-70 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs371469802; called by muse, varscan2
- IGLV3-1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs560070339; called by muse, mutect2, varscan2
- KIF3B | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV65227805; called by muse, mutect2, varscan2
- OR10G9 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66685778; called by muse, mutect2
- OR2V1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575995595, COSV61459090; called by muse, varscan2
- OR2V1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1309669997; called by muse, varscan2
- APCS | c.637G>T p.G213* | Nonsense Mutation (SNP) | VAF 154/290 reads (53%) | called by mutect2, varscan2
- BEST3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DUSP2 | c.285T>G p.S95R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- EGR1 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.6741T>G p.I2247M | Missense Mutation (SNP) | VAF 183/382 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- IGHV2-70 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- OR2V1 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PCDH9 | c.907T>G p.F303V | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS21 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN10 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 240/530 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3162G>A p.S1054= | Silent (SNP) | VAF 202/295 reads (68%) | called by muse, mutect2, varscan2
- BCL7A | c.51T>C p.D17= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99946945; called by muse, mutect2, varscan2
- DMRTA2 | c.717G>A p.S239= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs747667218, COSV101288891; called by muse, mutect2, varscan2
- IGLL5 | c.108T>C p.H36= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs561199169, COSV73251103; called by muse, mutect2, varscan2
- ITGA9 | c.1407C>T p.I469= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs774482781; called by muse, mutect2, varscan2
- LAMP5 | c.207T>G p.P69= | Silent (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- MCF2L | c.732G>A p.T244= (on ENST00000375608; = p.T212= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs757989358, COSV65053524; called by muse, mutect2, varscan2
- OR2V1 | c.555A>G p.L185= | Silent (SNP) | VAF 64/135 reads (47%) | called by muse, varscan2
- OR2V1 | c.96T>C p.V32= | Silent (SNP) | VAF 82/168 reads (49%) | called by muse, varscan2
- PKHD1L1 | c.9045G>A p.P3015= | Silent (SNP) | VAF 163/335 reads (49%) | catalogued as rs142162700; called by muse, mutect2, varscan2
- SOCS6 | c.63A>G p.E21= | Silent (SNP) | VAF 65/153 reads (42%) | called by muse, mutect2, varscan2
- URB1 | c.3282G>A p.P1094= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs377170267; called by muse, mutect2, varscan2
- C2orf69 | c.*2184G>C | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- CFHR3 | c.614-188C>T | Intron (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100807359; called by muse, mutect2
- DHRS13 | c.*360T>G | 3'UTR (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- DIO2 | c.*924del | 3'UTR (DEL) | VAF 78/148 reads (53%) | catalogued as rs896407541; called by mutect2, varscan2
- DLG4 | chr17:7219051 T>G | 5'Flank (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- DNER | c.*392A>G | 3'UTR (SNP) | VAF 70/121 reads (58%) | called by muse, mutect2, varscan2
- FAM13C | c.62+1320G>A | Intron (SNP) | VAF 117/233 reads (50%) | called by muse, mutect2, varscan2
- FAM53B | c.*2579A>T | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- FAM83A | c.*491T>A | 3'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- FTO | c.*78G>A | 3'UTR (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- FZD3 | c.*10747A>G | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- GATM | chr15:45378692 G>C | 5'Flank (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.*1157C>T | 3'UTR (SNP) | VAF 38/98 reads (39%) | catalogued as rs1311691013; called by muse, mutect2, varscan2
- IKZF2 | c.*1913A>T | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- KLHL8 | c.*2713A>C | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- NCAPD3 | chr11:134224326 del GG | 5'Flank (DEL) | VAF 49/171 reads (29%) | called by mutect2, pindel, varscan2
- NHS | c.*2994A>T | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- NKX2-8 | c.*887A>C | 3'UTR (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- PIM1 | c.-90C>G | 5'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- PLA2G2D | c.*1226C>T | 3'UTR (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- RGS3 | c.*361G>A | 3'UTR (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- SNAPC3 | c.*927G>A | 3'UTR (SNP) | VAF 61/169 reads (36%) | called by mutect2, varscan2
- SPTLC3 | c.*1661dup | 3'UTR (INS) | VAF 40/94 reads (43%) | called by mutect2, pindel, varscan2
- ZNF451 | c.3070+368C>T | Intron (SNP) | VAF 51/98 reads (52%) | catalogued as rs923314314; called by muse, mutect2, varscan2
- ZNF704 | c.*2781G>A | 3'UTR (SNP) | VAF 50/100 reads (50%) | catalogued as rs781631102; called by mutect2, varscan2
